Surgical pathology report (de-identified scan), TCGA case TCGA-2Y-A9GX, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Y-A9GX-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Gender: M
Reported:
Submitting Physicians:
Pathologist:
Intraop Pathologist:
Performing Physician:

Service:

Received:

CLINICAL HISTORY:
HEPATOCELLULAR CARCINOMA

PREOPERATIVE DIAGNOSIS:
NA

SPECIMEN TYPE(S):
A: NORMAL CARTILAGE
B: SEGMENT 7 LIVER

FINAL DIAGNOSIS:
A. CARTILAGE, SITE NOT SPECIFIED, EXCISION:
Cartilage and fibroadipose connective tissue with no evidence of malignancy.
B. LIVER, SEGMENT 7, SEGMENTECTOMY:
Moderately differentiated hepatocellular carcinoma, extending to the inked
parenchymal margin (see Key Pathological Findings).

KEY PATHOLOGICAL FINDINGS

Specimen type:	Segmentectomy
Tumor configuration:	Modular
Tumor size:	4.0 x 3.7 x 3.3 cm.
Histologic type:	Hepatocellular carcinoma
Histologic grade:	Moderately differentiated
Tumor necrosis:	Not identified
Extent of invasion:	Cannot be assessed
Perineural invasion:	Not identified
Parenchymal margin:	Tumor present at inked margin
Bile duct margin:	Cannot be assessed
Other margins:	Cannot be assessed
Venous (large vessel) invasion:	Not identified
Additional pathologic findings:	Micro and macrovesicular steatosis.
	Bridging fibrosis.
Lymph nodes:	None identified
Pathologic stages:	T1NXMX

I, the attending pathologist, personally reviewed the entire
pathology case and rendered the final diagnosis. Electronically Signed out by

OTHER RELATED CLINICAL DATA:

ICD-O-3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
JW 4/28/14

[page 2 of 2]
NA

INTRAOPERATIVE DIAGNOSIS:

GROSS EXAMINATION:

- B. SEGMENT 7 AND LIVER.
B1: Tumor close to margin.

COMMENT: This gross diagnosis/result was communicated to and acknowledged by
in

I, M.D., have performed the intraoperative
consultation and issued the above diagnoses.

GROSS DESCRIPTION:

- A. The specimen is labeled "normal cartilage." The specimen consists of 4.0 x 0.6 x 0.5 cm rib cartilage with moderate amount of adjacent tan-pale yellow to tan-pink, soft to rubbery fibroadipose tissue and muscle. The specimen measures in overall dimension 4.0 x 1.5 x 0.6 cm. No tissue is submitted to the Tissue Procurement Laboratory. The remainder of the specimen is submitted in 2 cassettes A1-A2.
- B. The specimen is labeled "segment 7 - liver, check margins." The specimen consists of an irregular, unoriented fragment of liver parenchyma measuring 10.0 x 6.0 x 3.3 cm. The capsule of the specimen is tan-red/brown, smooth, glistening. The resection margin is shaggy and inked blue. The specimen is serially sectioned to reveal an irregular, ill-defined lobulated intraparenchymal tumor which is measuring 4.0 x 3.7 x 3.3 cm. The tumor is less than 0.1 cm from the inked resection margin. The remaining parenchyma of the liver is grossly unremarkable. The tumor is also 0.1 cm from the closest capsule. Representative sections of the specimen are submitted to the Tissue Procurement Laboratory. Representative sections of the specimen are submitted in 3 cassettes as follows:
- B1-B5: Tumor with closest parenchymal resection margin
B6-B7: Tumor with closest capsule
B8: Grossly unremarkable liver parenchyma

Source: NCI Genomic Data Commons file 490cce3e-93ba-403e-aff3-7e098a29aec1 (TCGA-2Y-A9GX.92541202-F81A-428F-8EF5-19A7C82CC31F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).